Somatic mutation profile of tumor specimen TCGA-T9-A92H-01A (aliquot TCGA-T9-A92H-01A-11D-A36X-10) from TCGA case TCGA-T9-A92H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.3 years (30,058 days).
Specimen TCGA-T9-A92H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2083884d-5c1f-497c-b394-bcfc3db309a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T9-A92H-10A (Blood Derived Normal), aliquot TCGA-T9-A92H-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e99c355-9f73-4561-9de3-478251105387

The open-access MAF lists 193 somatic variants for this specimen: 142 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 47, Nonsense Mutation 10, Splice Site 5, Frame Shift Ins 3, RNA 2, Frame Shift Del 2, Intron 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 35/189 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTTP | c.1867+1G>A p.X623_splice | Splice Site (SNP) | VAF 49/101 reads (49%) | catalogued as rs764189338, CS952442, COSV55505008; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.555dup p.P186Tfs*2 | Frame Shift Ins (INS) | VAF 24/83 reads (29%) | catalogued as rs766524637; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 193/388 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SCN5A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as rs61737825, CM055529, COSV100349117; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 63/76 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55595275, COSV55596464, COSV99792434; called by muse, mutect2, varscan2
- ABCF1 | c.1995T>A p.S665R (on ENST00000326195 / NM_001025091.2; = p.S627R on NM_001090.3) | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58227754; called by muse, mutect2, varscan2
- ABHD16B | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769256438, COSV99410753; called by muse, varscan2
- ADGRL2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99589805; called by muse, mutect2, varscan2
- AK5 | c.662C>T p.P221L (on ENST00000354567 / NM_174858.3; = p.P195L on NM_012093.4) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100481469, COSV100481518; called by muse, mutect2, varscan2
- ALDH8A1 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV99664819; called by muse, mutect2, varscan2
- ALKBH4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs765883433, COSV99479403; called by muse, varscan2
- ANAPC4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.417); catalogued as COSV100194129; called by muse, mutect2, varscan2
- ANGPT4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101124776; called by muse, mutect2, varscan2
- ATG2B | c.4537A>C p.M1513L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99952114; called by muse, mutect2, varscan2
- B3GALT1 | c.71G>C p.S24T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV100002860; called by muse, mutect2
- B3GNT2 | c.105A>C p.K35N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as COSV100114228; called by muse, mutect2, varscan2
- BCL11B | c.2101C>T p.L701F (on ENST00000357195 / NM_001282237.2; = p.L630F on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as rs1273146364, COSV100595651; called by muse, mutect2, varscan2
- C4orf50 | c.715C>A p.P239T (on ENST00000324058; = p.P1471T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.624); catalogued as COSV100135972; called by muse, mutect2, varscan2
- CALHM6 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV100889454; called by muse, mutect2, varscan2
- CCDC120 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 112/121 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100900656; called by muse, mutect2, varscan2
- CCDC157 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100199780; called by muse, mutect2, varscan2
- CD93 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV99849321; called by muse, mutect2, varscan2
- CDC73 | c.1316+1G>A p.X439_splice | Splice Site (SNP) | VAF 88/196 reads (45%) | catalogued as COSV100813908; called by muse, mutect2, varscan2
- CELSR1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771567986, COSV53083605; called by muse, mutect2, varscan2
- CFAP43 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 80/197 reads (41%) | catalogued as COSV99530826; called by muse, mutect2, varscan2
- CLASP2 | c.1982C>A p.A661E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV56290117; called by muse, mutect2, varscan2
- CLEC1A | c.834A>T p.E278D | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); catalogued as COSV100191536; called by muse, mutect2, varscan2
- CMYA5 | c.8785G>A p.V2929M | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs1403525106, COSV101484156; called by muse, mutect2, varscan2
- CNST | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs773196569, COSV100829878, COSV100829888; called by muse, mutect2, varscan2
- COL19A1 | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 17/131 reads (13%) | catalogued as COSV100506614; called by muse, mutect2, varscan2
- COL19A1 | c.845A>T p.K282I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100506616; called by muse, mutect2, varscan2
- COL20A1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58921598; called by muse, mutect2, varscan2
- CPSF1 | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100450551; called by muse, mutect2, varscan2
- CRMP1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs752604466, COSV61478781; called by muse, mutect2, varscan2
- CRYBG1 | c.4722G>A p.W1574* | Nonsense Mutation (SNP) | VAF 35/173 reads (20%) | catalogued as rs559044700, COSV100954541; called by muse, mutect2, varscan2
- DAPK1 | c.1376A>C p.D459A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100802168, COSV63784404; called by muse, mutect2, varscan2
- DCAF12L1 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100948357; called by muse, mutect2, varscan2
- DCTN2 | c.445C>A p.L149M (on ENST00000548249 / NM_001261413.2; = p.L154M on NM_006400.4) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100851705; called by muse, mutect2, varscan2
- DMD | c.5221T>G p.L1741V | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63747107, COSV63789783; called by muse, mutect2, varscan2
- DNMBP | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100143981; called by muse, mutect2, varscan2
- FAM124A | c.1548T>A p.D516E (on ENST00000322475 / NM_001242312.2; = p.D552E on NM_145019.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99696372; called by muse, mutect2, varscan2
- FAM222B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745936897, COSV100368622; called by muse, mutect2, varscan2
- FAT3 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs776497356, COSV99967398; called by muse, mutect2, varscan2
- FAT4 | c.14094C>A p.N4698K | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100629005, COSV100629070; called by muse, mutect2, varscan2
- FKBP1A | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101098379, COSV67750534; called by muse, mutect2, varscan2
- FLG2 | c.2677C>A p.Q893K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.346); catalogued as COSV66167177, COSV66174483; called by muse, mutect2, varscan2
- FLT4 | c.3208C>A p.R1070S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56112322, COSV99987558; called by muse, mutect2, varscan2
- GDF2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1555208722; called by muse, mutect2, varscan2
- GIP | c.116A>G p.H39R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as COSV100656952; called by muse, mutect2, varscan2
- GTF3C1 | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 78/443 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100649530; called by muse, mutect2, varscan2
- HAUS8 | c.30-1G>T p.X10_splice | Splice Site (SNP) | VAF 75/185 reads (41%) | catalogued as COSV99505355; called by muse, mutect2, varscan2
- HEATR9 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368450766; called by muse, mutect2, varscan2
- HLF | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776917251, COSV56828344, COSV99872274; called by muse, mutect2, varscan2
- HPDL | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1368552396, COSV100588068; called by muse, mutect2, varscan2
- HRNR | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs373072541; called by muse, mutect2, varscan2
- HTR2B | c.158A>T p.K53I | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV51449676; called by muse, mutect2, varscan2
- IL11 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs201003688, COSV52773087, COSV99215040; called by muse, mutect2, varscan2
- INTS14 | c.116T>A p.F39Y | Missense Mutation (SNP) | VAF 83/107 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100499993; called by muse, mutect2, varscan2
- IRX4 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV99180837; called by muse, mutect2, varscan2
- ITGA4 | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276492; called by muse, mutect2, varscan2
- KCNQ2 | c.1325G>A p.R442H (on ENST00000359125 / NM_172107.4; = p.R414H on NM_004518.6) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1262943594, COSV60547722; called by muse, mutect2, varscan2
- KIF26B | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs567573827, COSV63644906; called by muse, mutect2, varscan2
- KRT1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs757504428, COSV52864732; called by muse, mutect2, varscan2
- KRT3 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV100527136; called by muse, mutect2, varscan2
- LACTB | c.816A>T p.E272D | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99978980; called by muse, mutect2
- LAMC3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs372564761; called by muse, mutect2, varscan2
- LRRC17 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99978497; called by muse, mutect2, varscan2
- LYRM2 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | catalogued as rs375403975; called by muse, mutect2, varscan2
- MAGEB1 | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100975034; called by muse, mutect2, varscan2
- MAP3K21 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 125/232 reads (54%) | catalogued as COSV100786282, COSV64043822; called by muse, mutect2, varscan2
- MAST2 | c.3185C>A p.S1062* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100788385, COSV63617668; called by muse, mutect2, varscan2
- MGAT3 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV100361953; called by muse, mutect2, varscan2
- NBEA | c.2108T>A p.L703H | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100081622; called by muse, varscan2
- NIBAN3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746166080, COSV56308159; called by muse, mutect2, varscan2
- NLRC3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs565215801, COSV100073226, COSV57093481; called by muse, varscan2
- NLRP5 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs377588935; called by muse, mutect2, varscan2
- NPTXR | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100285484; called by muse, mutect2, varscan2
- OBSCN | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV99480589; called by muse, mutect2, varscan2
- OR14I1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs750087696, COSV61200547; called by muse, mutect2, varscan2
- OR1C1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV101376245; called by muse, mutect2, varscan2
- OR1G1 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100187561; called by muse, mutect2, varscan2
- OR4A5 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1477630829, COSV60523807; called by muse, varscan2
- OR51A4 | c.541T>A p.C181S | Missense Mutation (SNP) | VAF 146/1608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985287; called by muse, mutect2
- OR6C76 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100094135; called by muse, mutect2, varscan2
- P3H3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782631453, COSV99301391; called by muse, mutect2, varscan2
- PCDH10 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.778); catalogued as rs769806730, COSV52091054; called by muse, mutect2, varscan2
- PCDHA2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65366617; called by muse, mutect2, varscan2
- PCNX1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 73/108 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); catalogued as COSV99456097; called by muse, mutect2, varscan2
- PGLYRP3 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.022); catalogued as COSV99319787; called by muse, mutect2, varscan2
- PHLPP2 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100673747; called by muse, mutect2, varscan2
- PPA2 | c.902G>A p.R301H (on ENST00000341695 / NM_176869.3; = p.R272H on NM_006903.4) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs146599366, COSV100500587; called by muse, mutect2, varscan2
- PSD4 | c.2644T>C p.S882P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99831248; called by muse, mutect2, varscan2
- PSG7 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV101343281; called by muse, mutect2, varscan2
- PSME4 | c.1993A>C p.N665H | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101122551; called by muse, mutect2, varscan2
- PTPN13 | c.1383G>A p.P461= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as rs764178386, COSV57420701; called by muse, mutect2
- RALGAPB | c.4395C>A p.D1465E | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99485390; called by muse, mutect2, varscan2
- RASA2 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53946776, COSV99656307; called by muse, mutect2, varscan2
- RTN4 | c.3574G>T p.E1192* (on ENST00000337526 / NM_020532.5; = p.E199* on NM_007008.3) | Nonsense Mutation (SNP) | VAF 60/143 reads (42%) | catalogued as COSV100463381; called by muse, mutect2, varscan2
- RXFP3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs754698803, COSV57504049; called by muse, mutect2, varscan2
- SAMD12 | c.442G>C p.E148Q (on ENST00000409003 / NM_001349811.2; = p.E158Q on NM_001101676.2) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV101290352; called by muse, varscan2
- SCN7A | c.2981C>A p.A994D | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); catalogued as rs372297374; called by muse, mutect2, varscan2
- SEMA4D | c.1533C>A p.D511E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV100358497; called by muse, mutect2, varscan2
- SEPTIN5 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as rs370825391, COSV100820415; called by muse, mutect2, varscan2
- SFSWAP | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.063); catalogued as COSV99906197; called by muse, mutect2, varscan2
- SLC12A7 | c.1588C>A p.L530M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99370112; called by muse, mutect2, varscan2
- SLC27A6 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 226/601 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52480002, COSV99323024; called by muse, mutect2, varscan2
- SLC34A1 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499779; called by muse, varscan2
- SLC34A1 | c.1666G>C p.V556L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99499780; called by muse, varscan2
- SORL1 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99494338; called by muse, mutect2, varscan2
- SPATA16 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV100651360; called by muse, mutect2
- SPPL2A | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55940674, COSV99961680; called by muse, mutect2, varscan2
- SPTB | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs201849832, COSV101072234, COSV67630352; called by muse, mutect2, varscan2
- SPTLC3 | c.1114A>C p.S372R | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100982890, COSV65464481; called by muse, mutect2, varscan2
- STK31 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100669573; called by muse, mutect2, varscan2
- TBCCD1 | c.1634T>G p.L545R | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100112033; called by muse, mutect2
- TEX15 | c.5045T>C p.L1682S (on ENST00000256246; = p.L2065S on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56351350, COSV99821559; called by muse, mutect2, varscan2
- TEX15 | c.2430A>G p.I810M (on ENST00000256246; = p.I1193M on NM_001350162.2) | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.182); catalogued as COSV99821561; called by muse, mutect2, varscan2
- TMTC4 | c.532G>A p.A178T (on ENST00000376234 / NM_001350577.2; = p.A197T on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as rs1242637577, COSV100168762; called by muse, mutect2, varscan2
- TRPA1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.285); catalogued as COSV100084496; called by muse, mutect2, varscan2
- TRPC4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs544186577, COSV58999065; called by muse, mutect2, varscan2
- TSHZ3 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs142735417; called by muse, mutect2, varscan2
- TTBK1 | c.3349C>T p.Q1117* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99444956; called by muse, mutect2, varscan2
- TUT4 | c.1001A>T p.E334V | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99932514; called by muse, mutect2, varscan2
- UFD1 | c.189T>A p.Y63* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99597433; called by muse, mutect2, varscan2
- USP15 | c.2525G>A p.R842Q (on ENST00000280377 / NM_001351159.2; = p.R813Q on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739912; called by muse, mutect2, varscan2
- USP21 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.242); catalogued as rs373004398; called by muse, mutect2, varscan2
- VPS41 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100054011; called by muse, mutect2, varscan2
- WDR53 | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 311/626 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as COSV100218103; called by muse, mutect2, varscan2
- XIRP2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.172); catalogued as COSV99740003, COSV99744357; called by muse, mutect2, varscan2
- ZFP28 | c.751A>C p.N251H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100019686; called by muse, mutect2, varscan2
- ZNF106 | c.4451G>A p.R1484H | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773812298, COSV99782752; called by muse, mutect2, varscan2
- ZNF626 | c.915A>G p.I305M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.285); catalogued as COSV101656925; called by muse, mutect2, varscan2
- ZNF677 | c.612A>T p.R204S | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs1194233045, COSV100448026; called by muse, mutect2, varscan2
- MCM4 | c.196del p.D66Tfs*25 | Frame Shift Del (DEL) | VAF 41/97 reads (42%) | called by mutect2, pindel*, varscan2
- NALCN | c.1878del p.K626Nfs*19 | Frame Shift Del (DEL) | VAF 68/184 reads (37%) | called by mutect2, pindel, varscan2
- OR2A2 | c.305dup p.L102Ffs*19 | Frame Shift Ins (INS) | VAF 86/290 reads (30%) | called by mutect2, pindel, varscan2
- PRPSAP1 | c.735_736insGGGG p.P246Gfs*42 | Frame Shift Ins (INS) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- SLFN13 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.36); called by mutect2, varscan2
- TAF4B | c.2003-13_2006del p.X668_splice | Splice Site (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- ZNF689 | c.-15_8del | Translation Start Site (DEL) | VAF 113/221 reads (51%) | called by mutect2, varscan2
- ACTR1B | c.576C>T p.R192= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100008126; called by muse, mutect2, varscan2
- ADGRG4 | c.2826T>G p.T942= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99795902; called by muse, mutect2, varscan2
- AGT | c.840C>G p.T280= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV100794394; called by muse, mutect2, varscan2
- ALDH1B1 | c.1395C>T p.A465= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs765513995, COSV100890953; called by muse, mutect2, varscan2
- CD19 | c.1296C>T p.L432= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100218170; called by muse, mutect2, varscan2
- DCC | c.357A>T p.A119= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV100501097, COSV59087010; called by muse, mutect2, varscan2
- DOCK8 | c.2034T>C p.R678= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs761968450, COSV101209972; called by muse, mutect2, varscan2
- DOP1B | c.1020G>A p.L340= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV101215542; called by muse, mutect2, varscan2
- DTNBP1 | c.822C>T p.S274= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100160902; called by muse, mutect2, varscan2
- FBXO11 | c.834G>A p.G278= (on ENST00000403359 / NM_001190274.2; = p.G194= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/288 reads (35%) | catalogued as COSV100319629; called by muse, varscan2
- GDF10 | c.468C>T p.N156= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs782043433; called by muse, mutect2, varscan2
- HELZ2 | c.7314G>A p.A2438= (on ENST00000467148 / NM_001037335.2; = p.A1869= on NM_033405.3) | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs749696579, COSV64443224; called by muse, varscan2
- IL22RA1 | c.291C>T p.T97= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs772991905, COSV99583116; called by muse, mutect2, varscan2
- LDB3 | c.162C>T p.G54= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs757856121, COSV53947877; ClinVar: benign; called by muse, mutect2, varscan2
- LPCAT2 | c.1458T>C p.F486= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV100044960; called by muse, mutect2, varscan2
- LRRN1 | c.975C>G p.L325= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV100076403; called by muse, mutect2, varscan2
- MADD | c.3264T>C p.V1088= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100211615; called by muse, mutect2, varscan2
- MC2R | c.402C>T p.H134= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs139883463; called by muse, mutect2, varscan2
- MPND | c.1161C>G p.L387= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99515232; called by muse, mutect2, varscan2
- NAF1 | c.1326A>C p.P442= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs1211570776, COSV99919208; called by muse, mutect2, varscan2
- NCKAP1L | c.1594C>T p.L532= | Silent (SNP) | VAF 77/181 reads (43%) | catalogued as COSV99515261; called by muse, mutect2, varscan2
- NLRP5 | c.3450G>A p.T1150= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs376501237; called by muse, mutect2, varscan2
- NSMF | c.1155G>A p.E385= (on ENST00000371475 / NM_001130969.3; = p.E383= on NM_015537.4) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99689376; called by muse, mutect2, varscan2
- NXN | c.957C>T p.N319= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs777784278, COSV61093924; called by muse, mutect2, varscan2
- OR51A4 | c.768C>A p.I256= | Silent (SNP) | VAF 138/1502 reads (9%) | catalogued as COSV66749320; called by muse, mutect2
- OR6Q1 | c.508C>T p.L170= | Silent (SNP) | VAF 126/292 reads (43%) | catalogued as COSV100110133, COSV100110504; called by muse, mutect2
- PCF11 | c.4198C>T p.L1400= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as rs1222021467, COSV100018659; called by muse, mutect2, varscan2
- PCOLCE2 | c.486C>T p.S162= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs1191767741, COSV99930773; called by muse, mutect2, varscan2
- POU4F1 | c.165G>C p.L55= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV101020567; called by muse, mutect2
- PPP2R1A | c.672G>T p.A224= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs371185672, COSV100436331; called by muse, mutect2, varscan2
- PYGB | c.1389C>T p.I463= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs201316067, COSV53817337; called by muse, mutect2, varscan2
- RHPN1 | c.1707G>A p.A569= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs375100593, COSV56648374; called by muse, mutect2, varscan2
- RLBP1 | c.255G>A p.A85= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs557154377, COSV51529931; called by muse, mutect2, varscan2
- RTEL1 | c.3615C>T p.S1205= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs797045923, COSV99423109; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC23A2 | c.957C>T p.A319= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100595096; called by muse, mutect2, varscan2
- SLC41A1 | c.732C>T p.R244= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV100900422; called by muse, mutect2
- SSX2IP | c.321T>A p.L107= | Silent (SNP) | VAF 114/208 reads (55%) | catalogued as COSV100642622; called by muse, mutect2, varscan2
- SYT17 | c.1395C>T p.R465= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs375022285; called by muse, mutect2
- TARS1 | c.285G>A p.A95= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs779855795, COSV54311921; called by muse, mutect2, varscan2
- TCF19 | c.663C>T p.R221= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99463108; called by mutect2, varscan2
- TMEM176A | c.327G>T p.R109= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV99133817; called by muse, mutect2, varscan2
- TMEM92 | c.345G>A p.A115= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs753044477, COSV100305189; called by muse, mutect2, varscan2
- TRANK1 | c.3642C>T p.P1214= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as COSV100083486; called by muse, mutect2, varscan2
- VPS33A | c.732G>T p.L244= | Silent (SNP) | VAF 55/151 reads (36%) | catalogued as COSV99931427; called by muse, mutect2, varscan2
- VPS37B | c.558C>T p.T186= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs765717985, COSV53444539; called by muse, mutect2, varscan2
- WDR88 | c.1065G>T p.R355= | Silent (SNP) | VAF 101/244 reads (41%) | catalogued as COSV100866575; called by muse, mutect2, varscan2
- ZC3H13 | c.2211G>A p.R737= | Silent (SNP) | VAF 112/849 reads (13%) | catalogued as rs1369629022, COSV99668410; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1224C>T | Intron (SNP) | VAF 18/33 reads (55%) | catalogued as rs373191717; called by muse, mutect2, varscan2
- DLG2 | c.205-65794G>A | Intron (SNP) | VAF 19/82 reads (23%) | catalogued as rs552998302, COSV54619672; called by muse, mutect2, varscan2
- FRMPD2B | n.927G>A | RNA (SNP) | VAF 82/267 reads (31%) | catalogued as rs1241533490; called by muse, varscan2
- SLC66A1L | n.196T>A | RNA (SNP) | VAF 7/109 reads (6%) | catalogued as COSV100396549; called by muse, mutect2
